Somatic mutation profile of tumor specimen TARGET-20-PAPZIZ-09A (aliquot TARGET-20-PAPZIZ-09A-02D) from TARGET case TARGET-20-PAPZIZ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.4 years (5,611 days).
Specimen TARGET-20-PAPZIZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ec4df01-9a24-4184-ba11-552c378c693e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAPZIZ-14A (Bone Marrow Normal), aliquot TARGET-20-PAPZIZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72edcdb7-b5be-4fb7-907a-e6ce8587a38c

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FHDC1 | c.2885G>A p.S962N | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RUNX1 | c.*3052G>A | 3'UTR (SNP) | VAF 119/261 reads (46%) | called by muse, mutect2, varscan2
